Somatic mutation profile of tumor specimen TCGA-G9-6362-01A (aliquot TCGA-G9-6362-01A-11D-1786-08) from TCGA case TCGA-G9-6362, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 57.9 years (21,149 days).
Specimen TCGA-G9-6362-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cfb11bb0-8936-45f5-b3df-c35cbba87b18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G9-6362-10A (Blood Derived Normal), aliquot TCGA-G9-6362-10A-01D-1786-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8da894ef-7745-4ef7-b6a3-14211709fc92

The open-access MAF lists 41 somatic variants for this specimen: 22 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 17, Nonsense Mutation 3, Intron 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC11 | c.489G>C p.L163F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV62321209, COSV62321743; called by muse, mutect2, varscan2
- ASIC2 | c.434A>C p.H145P | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs754374656, COSV63294386; called by muse, mutect2, varscan2
- ATG10 | c.170C>G p.S57* | Nonsense Mutation (SNP) | VAF 31/284 reads (11%) | catalogued as COSV56422416; called by muse, mutect2, varscan2
- CDK5RAP2 | c.4573G>T p.E1525* | Nonsense Mutation (SNP) | VAF 5/87 reads (6%) | catalogued as COSV62571991; called by muse, mutect2
- CYB5R2 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 16/139 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs962632087, COSV100207342, COSV55085060; called by muse, mutect2, varscan2
- DNAJC5B | c.589A>T p.T197S | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.293); catalogued as COSV52535678; called by mutect2, varscan2
- EFEMP2 | c.632C>G p.A211G | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.59); catalogued as COSV57258874, COSV57261130; called by muse, mutect2
- FAM83H | c.730A>G p.S244G | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); catalogued as COSV66353410; called by muse, mutect2
- FUT10 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as COSV59449780; called by muse, mutect2
- HTR1A | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as COSV60499784; called by muse, mutect2
- LELP1 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as rs573106359, COSV64202277; called by muse, mutect2
- MED14 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT tolerated (0.43); PolyPhen benign (0.151); catalogued as rs759092950, COSV61355817; called by muse, mutect2, varscan2
- MYO15A | c.2849G>A p.R950H | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); catalogued as rs1255530106, COSV52762080, COSV99231653; called by mutect2, varscan2
- NTM | c.715G>T p.G239W | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1172152980, COSV66172376; called by muse, mutect2
- OR4D5 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.05); catalogued as rs564572858, COSV58305578; called by muse, mutect2, varscan2
- PRDM9 | c.1162C>T p.H388Y | Missense Mutation (SNP) | VAF 57/157 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV57002339; called by muse, mutect2, varscan2
- SFRP2 | c.248T>C p.V83A | Missense Mutation (SNP) | VAF 24/157 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV56836722; called by muse, mutect2, varscan2
- TBXA2R | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs201738444, COSV64343125; called by muse, mutect2, varscan2
- TTN | c.70562G>C p.S23521T (on ENST00000591111; = p.S16097T on NM_003319.4) | Missense Mutation (SNP) | VAF 37/109 reads (34%) | PolyPhen benign (0.015); catalogued as rs750324994, COSV59882761; called by muse, mutect2, varscan2
- ZMYM3 | c.3887C>G p.P1296R | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58736032; called by muse, mutect2, varscan2
- ZMYM3 | c.3886C>A p.P1296T | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58736054; called by muse, mutect2, varscan2
- ZNF622 | c.457A>T p.K153* | Nonsense Mutation (SNP) | VAF 16/133 reads (12%) | catalogued as COSV58073357; called by muse, mutect2, varscan2
- BHMT | c.204A>T p.S68= | Silent (SNP) | VAF 37/79 reads (47%) | catalogued as COSV57153548; called by muse, mutect2, varscan2
- CBX8 | c.768G>A p.S256= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs1390059575, COSV53935394; called by muse, mutect2, varscan2
- COQ6 | c.796T>C p.L266= | Silent (SNP) | VAF 57/141 reads (40%) | catalogued as rs113814754, COSV53177877; called by muse, mutect2, varscan2
- FIBCD1 | c.1116C>T p.S372= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs142382814; called by muse, mutect2, varscan2
- H2AC4 | c.192G>A p.L64= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV52517845; called by muse, mutect2, varscan2
- INTS10 | c.1500G>A p.A500= | Silent (SNP) | VAF 14/58 reads (24%) | catalogued as rs758862755, COSV67603526; called by muse, mutect2
- MXRA5 | c.8448C>T p.L2816= | Silent (SNP) | VAF 21/24 reads (88%) | catalogued as rs774460007, COSV54223515; called by muse, mutect2, varscan2
- OR10K2 | c.273C>A p.T91= | Silent (SNP) | VAF 18/314 reads (6%) | catalogued as COSV59220389; called by muse, mutect2
- OR5T2 | c.921G>A p.S307= | Silent (SNP) | VAF 7/159 reads (4%) | catalogued as rs201143815, COSV57587788; called by muse, mutect2
- P4HTM | c.360G>A p.G120= | Silent (SNP) | VAF 3/35 reads (9%) | catalogued as COSV59085984; called by muse, mutect2
- PCDHGA1 | c.927C>T p.F309= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs148638556; called by muse, mutect2, varscan2
- PKHD1 | c.2163G>A p.T721= | Silent (SNP) | VAF 8/112 reads (7%) | catalogued as rs1380077729, COSV61860069; called by muse, mutect2
- SLC8B1 | c.1188C>A p.I396= | Silent (SNP) | VAF 54/114 reads (47%) | catalogued as COSV52526232; called by muse, mutect2, varscan2
- TTN | c.89307C>T p.S29769= (on ENST00000591111; = p.S22345= on NM_003319.4) | Silent (SNP) | VAF 17/133 reads (13%) | catalogued as rs373502790; ClinVar: likely benign; called by muse, mutect2, varscan2
- TXNIP | c.456T>C p.N152= | Silent (SNP) | VAF 33/164 reads (20%) | catalogued as COSV65219916; called by muse, mutect2, varscan2
- UHRF1BP1 | c.999G>T p.L333= | Silent (SNP) | VAF 33/113 reads (29%) | catalogued as COSV51952595; called by muse, mutect2, varscan2
- ZMYM1 | c.1590A>G p.Q530= | Silent (SNP) | VAF 20/240 reads (8%) | catalogued as rs567658292, COSV63250423; called by muse, mutect2
- RDM1 | c.667+44A>C | Intron (SNP) | VAF 15/116 reads (13%) | called by muse, mutect2, varscan2
- SLC25A25 | c.262-9199A>G | Intron (SNP) | VAF 109/281 reads (39%) | catalogued as COSV66088069; called by muse, mutect2, varscan2
